Somatic mutation profile of tumor specimen TCGA-CN-4723-01A (aliquot TCGA-CN-4723-01A-01D-1434-08) from TCGA case TCGA-CN-4723, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.9 years (24,815 days).
Specimen TCGA-CN-4723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 189dd652-ed7c-4f41-b434-4f52d9d2b5a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4723-10A (Blood Derived Normal), aliquot TCGA-CN-4723-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c26d67d7-db1e-4c39-85da-a61fe6f8a19a

The open-access MAF lists 919 somatic variants for this specimen: 661 protein-altering or splice-affecting, 236 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 563, Silent 236, Nonsense Mutation 72, Splice Site 11, Intron 10, Frame Shift Del 7, RNA 5, Splice Region 3, 3'UTR 3, 5'UTR 3, Frame Shift Ins 3, Nonstop Mutation 1.

Variants (750 of 919; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLG | c.5930C>G p.S1977* | Nonsense Mutation (SNP) | VAF 300/851 reads (35%) | catalogued as rs140980397; ClinVar: pathogenic; called by muse, varscan2
- NFE2L2 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 33/104 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 30/196 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 43/99 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.1716C>G p.F572L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100588909; called by muse, mutect2
- ABCA1 | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 103/371 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV101037493; called by muse, mutect2, varscan2
- ABCA13 | c.5626G>C p.E1876Q | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV101330150; called by muse, mutect2, varscan2
- ABCA13 | c.6239C>G p.S2080C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101330151; called by muse, mutect2, varscan2
- ABCA2 | c.3934G>A p.E1312K (on ENST00000614293; = p.E1282K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.726); catalogued as rs764897224, COSV55799388, COSV99688272; called by muse, mutect2, varscan2
- ABCA3 | c.2654G>T p.G885V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100069004; called by muse, mutect2, varscan2
- ABCB7 | c.1567G>A p.E523K (on ENST00000373394 / NM_001271696.3; = p.E524K on NM_004299.6) | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99504712; called by muse, mutect2, varscan2
- ABCG8 | c.711C>A p.D237E | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99700155; called by muse, mutect2, varscan2
- AC127029.3 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs780941513, COSV60111419; called by muse, mutect2, varscan2
- ACAD10 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100564509; called by muse, mutect2, varscan2
- ACVR1C | c.1049C>G p.S350* | Nonsense Mutation (SNP) | VAF 77/235 reads (33%) | catalogued as COSV54645986, COSV54649361; called by muse, mutect2, varscan2
- ADAM12 | c.573G>C p.K191N | Missense Mutation (SNP) | VAF 39/428 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100901219, COSV64115506, COSV64116287; called by muse, mutect2
- ADAM22 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs370626885, COSV55973954; called by muse, mutect2, varscan2
- ADAM23 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV100008518; called by muse, mutect2, varscan2
- ADCY1 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV99812740; called by muse, mutect2, varscan2
- ADCYAP1 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV52485715, COSV99327591; called by muse, mutect2, varscan2
- ADGRV1 | c.6445G>C p.D2149H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1247341196, COSV101316347; called by muse, mutect2, varscan2
- ADH5 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99596334; called by muse, mutect2, varscan2
- AGAP1 | c.1822G>A p.E608K (on ENST00000304032 / NM_001037131.3; = p.E555K on NM_014914.5) | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs370536569; called by muse, mutect2, varscan2
- AGBL2 | c.2492C>T p.S831L | Missense Mutation (SNP) | VAF 126/488 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV100102013; called by muse, mutect2, varscan2
- AGO3 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.67); catalogued as COSV99869228; called by muse, mutect2
- AGXT2 | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 46/234 reads (20%) | catalogued as COSV51484069, COSV99183846; called by muse, mutect2, varscan2
- AKAP11 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99214240; called by muse, varscan2
- AKAP3 | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99962538; called by muse, mutect2, varscan2
- AKAP6 | c.3636G>A p.M1212I | Missense Mutation (SNP) | VAF 118/217 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99803597; called by muse, mutect2, varscan2
- AKAP6 | c.4369G>A p.E1457K | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99803600; called by muse, mutect2, varscan2
- ALAS2 | c.1534G>C p.G512R | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100238548, COSV99043816; called by muse, mutect2, varscan2
- ALDH7A1 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1197981680, COSV101297479; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDOB | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 75/296 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV100878964, COSV66397513; called by muse, mutect2, varscan2
- ALMS1 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100043396; called by muse, mutect2, varscan2
- AMDHD1 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57137617, COSV99900493; called by muse, mutect2, varscan2
- ANK2 | c.10567G>C p.E3523Q | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV100003565; called by muse, mutect2, varscan2
- AP2B1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52003591; called by muse, mutect2, varscan2
- AP2M1 | c.294G>C p.E98D | Missense Mutation (SNP) | VAF 50/420 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV53047507, COSV99490874; called by muse, mutect2, varscan2
- APAF1 | c.2172C>A p.F724L (on ENST00000551964 / NM_181861.2; = p.F713L on NM_001160.3) | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100244362; called by muse, mutect2, varscan2
- APBA1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs1172862703, COSV99596922; called by muse, mutect2, varscan2
- APC | c.6217G>A p.G2073S | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99969597; called by muse, mutect2, varscan2
- APC | c.7933T>C p.Y2645H | Missense Mutation (SNP) | VAF 104/280 reads (37%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.853); catalogued as COSV57370876; called by muse, mutect2, varscan2
- APP | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV100696174, COSV60993194; called by muse, mutect2, varscan2
- AQP9 | c.335G>C p.G112A | Missense Mutation (SNP) | VAF 81/374 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV54968435, COSV99583163; called by muse, mutect2, varscan2
- ARHGAP17 | c.1143C>A p.F381L | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99253911; called by muse, mutect2, varscan2
- ARHGAP18 | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100936429; called by muse, mutect2, varscan2
- ARHGAP24 | c.1765G>A p.E589K (on ENST00000395184 / NM_001025616.3; = p.E496K on NM_031305.3) | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV99982311; called by muse, mutect2, varscan2
- ARHGAP45 | c.1943C>A p.S648Y | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100491023; called by muse, mutect2, varscan2
- ARHGEF10L | c.1758G>C p.E586D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV99393615; called by muse, mutect2
- ARHGEF28 | c.4192G>C p.E1398Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV99709863; called by muse, mutect2, varscan2
- ARID1A | c.4747C>T p.P1583S | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.932); catalogued as COSV100252980; called by muse, mutect2, varscan2
- ATP13A3 | c.3400C>T p.Q1134* | Nonsense Mutation (SNP) | VAF 51/251 reads (20%) | catalogued as COSV99757514; called by muse, mutect2, varscan2
- ATP13A4 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 141/230 reads (61%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV99795127; called by muse, mutect2, varscan2
- ATP1A2 | c.2589C>G p.F863L | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV100768099, COSV63403963, COSV63404309; called by muse, mutect2, varscan2
- ATP6V0D2 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 42/287 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as COSV99572023; called by muse, mutect2, varscan2
- ATRN | c.3641C>G p.S1214* | Nonsense Mutation (SNP) | VAF 9/149 reads (6%) | catalogued as COSV99496324; called by muse, mutect2
- ATRX | c.4657C>G p.H1553D | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV100971283; called by muse, mutect2, varscan2
- B3GALT4 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 97/184 reads (53%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.943); catalogued as COSV101005695; called by muse, mutect2, varscan2
- B4GALT6 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52703957, COSV99380273; called by muse, mutect2, varscan2
- BAG3 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 33/100 reads (33%) | catalogued as COSV100958283; called by muse, mutect2, varscan2
- BAZ2B | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100600909; called by muse, varscan2
- BAZ2B | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100600911, COSV58604399, COSV58606395; called by muse, varscan2
- BEGAIN | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767015; called by muse, mutect2, varscan2
- BICD2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.266); catalogued as rs770331418, COSV100794188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP5 | c.915C>G p.F305L | Missense Mutation (SNP) | VAF 138/384 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV100896252, COSV63701723; called by muse, mutect2, varscan2
- BRPF1 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs371562413; called by muse, mutect2, varscan2
- BRWD1 | c.4517C>G p.S1506* | Nonsense Mutation (SNP) | VAF 35/127 reads (28%) | catalogued as COSV100313910; called by muse, mutect2
- BRWD3 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100956411; called by muse, mutect2, varscan2
- BTN2A2 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV100760566, COSV61856531; called by muse, mutect2, varscan2
- BTNL8 | c.443G>C p.R148T | Missense Mutation (SNP) | VAF 150/615 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99180554; called by muse, mutect2, varscan2
- BTNL8 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as COSV99180556; called by muse, mutect2, varscan2
- C11orf49 | c.451+1G>A p.X151_splice | Splice Site (SNP) | VAF 69/298 reads (23%) | catalogued as COSV99562601; called by muse, mutect2, varscan2
- C19orf12 | c.291G>C p.Q97H (on ENST00000392278 / NM_001031726.3; = p.Q86H on NM_031448.6) | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100080632; called by muse, mutect2
- C6orf118 | c.1394G>C p.R465T | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.404); catalogued as COSV100024879, COSV100024951, COSV57813264; called by muse, mutect2, varscan2
- C9 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV99662403; called by muse, mutect2
- CACNA1C | c.4486G>C p.E1496Q | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as CM152262, COSV100221579; called by muse, mutect2, varscan2
- CACNA1D | c.1756C>G p.L586V (on ENST00000350061 / NM_001128840.3; = p.L606V on NM_000720.4) | Missense Mutation (SNP) | VAF 12/309 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99859580; called by muse, mutect2
- CACNA1H | c.4575G>C p.Q1525H | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.722); catalogued as COSV100673344; called by muse, mutect2, varscan2
- CACNA1I | c.3765C>G p.I1255M | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100361247; called by muse, mutect2, varscan2
- CACNA2D1 | c.2060T>G p.I687S (on ENST00000356253 / NM_001366867.1; = p.I675S on NM_000722.4) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100667072; called by muse, mutect2
- CASKIN1 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100624367; called by muse, mutect2, varscan2
- CASKIN2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs199526332; called by muse, varscan2
- CATSPER2 | c.561G>A p.L187= | Splice Region (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100390944; called by mutect2, varscan2
- CATSPER3 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99254279; called by muse, mutect2, varscan2
- CC2D1B | c.1972C>G p.Q658E | Missense Mutation (SNP) | VAF 69/398 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99430199; called by muse, mutect2, varscan2
- CCDC106 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.149); catalogued as rs778004878, COSV58275452; called by muse, mutect2, varscan2
- CCDC73 | c.665C>G p.S222* | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100068152; called by muse, mutect2, varscan2
- CCDC97 | c.537C>G p.F179L | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99523838; called by muse, mutect2, varscan2
- CCNB1IP1 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 122/208 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs774088761, COSV100738633; called by muse, mutect2, varscan2
- CCPG1 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.059); catalogued as COSV100197386; called by muse, mutect2, varscan2
- CCT7 | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as COSV99241106; called by muse, mutect2, varscan2
- CD180 | c.1263G>C p.Q421H | Missense Mutation (SNP) | VAF 82/323 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99842345; called by muse, mutect2, varscan2
- CD19 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100218242; called by muse, mutect2
- CD300LB | c.209G>C p.G70A | Missense Mutation (SNP) | VAF 85/334 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV100075547, COSV58726911; called by muse, mutect2, varscan2
- CD3D | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454085519, COSV99416859; called by muse, mutect2, varscan2
- CDC27 | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as rs1378929700; called by muse, mutect2, varscan2
- CDC27 | c.1658C>T p.S553L | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99296043; called by muse, varscan2
- CDCA7L | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.476); catalogued as rs1313733569, COSV100651201; called by muse, mutect2, varscan2
- CDON | c.3721G>T p.E1241* (on ENST00000392693 / NM_001243597.2; = p.E1218* on NM_016952.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV54996284, COSV99701836; called by muse, mutect2, varscan2
- CELSR1 | c.8578C>T p.P2860S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99419642; called by muse, mutect2
- CELSR2 | c.4892C>G p.S1631W | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV99604575; called by muse, mutect2, varscan2
- CEMIP2 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 33/149 reads (22%) | catalogued as COSV100987485; called by muse, mutect2, varscan2
- CENPE | c.6646C>T p.Q2216* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99478842; called by muse, mutect2, varscan2
- CEP135 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV99954787; called by muse, mutect2, varscan2
- CEP170 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100317677; called by muse, mutect2
- CFAP47 | c.1305C>G p.I435M | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as COSV52883892; called by muse, mutect2, varscan2
- CFAP69 | c.1061G>C p.G354A | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.359); catalogued as COSV100290377, COSV60187649; called by muse, mutect2, varscan2
- CFLAR | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100009771; called by muse, mutect2, varscan2
- CGN | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | catalogued as COSV99642699; called by muse, mutect2, varscan2
- CHD1L | c.2321-1G>C p.X774_splice | Splice Site (SNP) | VAF 17/131 reads (13%) | catalogued as rs1553970395, COSV100787555; called by muse, mutect2, varscan2
- CHRNA6 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200497100, COSV52379746, COSV99373382; called by muse, mutect2, varscan2
- CIART | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV99290398; called by muse, mutect2, varscan2
- CILP | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs369696446, COSV99972848; called by muse, mutect2, varscan2
- CLEC18C | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100032225; called by mutect2, varscan2
- CLIC6 | c.1444G>C p.E482Q (on ENST00000360731 / NM_001317009.2; = p.E464Q on NM_053277.3) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100659299; called by muse, mutect2, varscan2
- CNGB3 | c.1750C>G p.L584V | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100181367, COSV100182834; called by muse, mutect2, varscan2
- COBL | c.3088C>G p.Q1030E | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs968465295, COSV99473794; called by muse, mutect2, varscan2
- COL10A1 | c.686G>C p.G229A | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs202057046, COSV99684404; called by muse, mutect2, varscan2
- COL1A1 | c.2491G>A p.D831N | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.602); catalogued as COSV56804250; called by muse, mutect2, varscan2
- COL1A2 | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139199272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL3A1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs863223362, COSV58591872; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- COQ7 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100430560; called by muse, mutect2, varscan2
- COQ8A | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100825785; called by muse, mutect2
- CPLX4 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100231516, COSV55314238; called by muse, mutect2, varscan2
- CPNE4 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101456789, COSV70194257; called by muse, varscan2
- CPS1 | c.3511G>C p.E1171Q | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as COSV99243842; called by muse, mutect2, varscan2
- CSGALNACT2 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100989840; called by muse, mutect2, varscan2
- CSMD1 | c.2863C>G p.L955V (on ENST00000520002; = p.L954V on NM_033225.6) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770099024, COSV100152639; called by muse, mutect2, varscan2
- CSMD3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.967); catalogued as rs536561292, COSV52113015; called by muse, mutect2, varscan2
- CSNK1E | c.611T>A p.M204K | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100725075; called by muse, mutect2, varscan2
- CSNK1E | c.610A>C p.M204L | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.817); catalogued as COSV100725076, COSV63290601; called by muse, mutect2, varscan2
- CTTN | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV100098237; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV54744348; called by muse, mutect2, varscan2
- CXXC1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99497023; called by muse, mutect2, varscan2
- CXorf21 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 115/218 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as COSV100973348; called by muse, mutect2, varscan2
- CYLD | c.330C>A p.F110L | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100282686; called by muse, mutect2, varscan2
- CYP2E1 | c.447G>C p.R149S | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99429178; called by muse, mutect2, varscan2
- DAPK1 | c.3352G>A p.D1118N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.306); catalogued as rs1179480719, COSV100802599; called by muse, mutect2, varscan2
- DARS2 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99508866; called by muse, mutect2, varscan2
- DCAF6 | c.1805C>G p.S602C (on ENST00000312263 / NM_001349778.1; = p.S622C on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV100394714; called by muse, mutect2, varscan2
- DCAF8L1 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.406); catalogued as COSV101491527; called by muse, mutect2, varscan2
- DDI1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV100158121; called by muse, mutect2, varscan2
- DDN | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100305357; called by muse, mutect2, varscan2
- DDX1 | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51839004, COSV99246825; called by muse, mutect2, varscan2
- DDX11 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.02); catalogued as COSV52504451, COSV52506209; called by muse, mutect2, varscan2
- DDX24 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1449540094, COSV100428096; called by muse, mutect2, varscan2
- DDX3Y | c.1450C>A p.Q484K | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.164); catalogued as COSV100267577; called by muse, mutect2
- DDX58 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV101153166; called by muse, mutect2
- DEUP1 | c.1082C>G p.S361C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV99977523; called by muse, mutect2, varscan2
- DGKK | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101053166; called by muse, mutect2, varscan2
- DHX37 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV100439437; called by muse, mutect2, varscan2
- DHX57 | c.2845G>C p.E949Q | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99769869; called by muse, mutect2, varscan2
- DIP2B | c.3172G>C p.E1058Q | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV99999169; called by muse, mutect2, varscan2
- DISC1 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV99698405; called by muse, mutect2, varscan2
- DLC1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 115/450 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99364914; called by muse, mutect2, varscan2
- DNAH3 | c.10038C>G p.I3346M | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV54501104, COSV99769903; called by muse, mutect2, varscan2
- DNAH7 | c.10462C>T p.Q3488* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100416962; called by muse, mutect2, varscan2
- DNAH9 | c.12130G>T p.E4044* | Nonsense Mutation (SNP) | VAF 140/574 reads (24%) | catalogued as COSV52378033, COSV99307532; called by muse, mutect2, varscan2
- DOCK9 | c.1644C>G p.I548M (on ENST00000376460 / NM_001366676.2; = p.I549M on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/347 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV100240676; called by muse, mutect2, varscan2
- DPM1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs546651949, COSV100857750; called by muse, mutect2
- DTNBP1 | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100161070; called by muse, varscan2
- DUOX1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs879029084, COSV50993197, COSV50994094; called by muse, mutect2, varscan2
- DYRK1A | c.1785G>C p.Q595H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100118189; called by muse, mutect2, varscan2
- DYRK4 | c.424C>A p.H142N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99157706; called by muse, mutect2, varscan2
- DZIP3 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV100847992; called by muse, mutect2, varscan2
- DZIP3 | c.2680C>G p.H894D | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1245874668, COSV100847994; called by muse, mutect2, varscan2
- EDN2 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs759554381, COSV101006356; called by muse, mutect2, varscan2
- EEF2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as rs778994144, COSV58580138; called by muse, mutect2, varscan2
- EID2B | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV58319122; called by muse, mutect2, varscan2
- EIF4G1 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 14/143 reads (10%) | catalogued as COSV100072219; called by muse, mutect2, varscan2
- EMILIN1 | c.1474C>G p.Q492E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV99566482; called by muse, mutect2, varscan2
- EPG5 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs746081416, COSV99957897; called by muse, mutect2, varscan2
- EPPK1 | c.6431G>A p.R2144K | Missense Mutation (SNP) | VAF 77/491 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV101599713, COSV101599935; called by muse, mutect2, varscan2
- ERAP2 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.798); catalogued as rs199510383; called by muse, mutect2, varscan2
- ERBB3 | c.3605G>A p.R1202Q | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs373454755; called by muse, mutect2, varscan2
- ERN2 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV99890598, COSV99892176; called by muse, mutect2, varscan2
- ERO1B | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV100524175; called by muse, mutect2, varscan2
- ESCO1 | c.1303C>G p.Q435E | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99332510; called by muse, mutect2, varscan2
- ESRP1 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs760981296, COSV64413228; called by muse, mutect2, varscan2
- ESX1 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 131/271 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.177); catalogued as COSV101006494; called by muse, mutect2, varscan2
- ESYT3 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 64/233 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs62282904, COSV100004943; called by muse, mutect2, varscan2
- ETS2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs755069743, COSV100711230, COSV62872913; called by muse, mutect2, varscan2
- FAAP24 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV99578147; called by muse, mutect2, varscan2
- FAM135B | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52737724, COSV99424890, COSV99426619; called by muse, mutect2, varscan2
- FAM13B | c.2713C>G p.L905V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50370540, COSV99221735; called by muse, mutect2, varscan2
- FAM184A | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100138215; called by muse, mutect2, varscan2
- FAM53B | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV100484232; called by muse, mutect2, varscan2
- FAM81B | c.1068G>C p.Q356H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.044); catalogued as COSV99353124; called by muse, mutect2, varscan2
- FARSB | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99918581; called by muse, mutect2, varscan2
- FASTKD5 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV99417824; called by muse, mutect2, varscan2
- FAT4 | c.13813G>C p.E4605Q | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); catalogued as COSV100629758; called by muse, mutect2, varscan2
- FBXO16 | c.167G>C p.R56T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100672450; called by muse, mutect2, varscan2
- FCGR3A | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs755776791, COSV100914695; called by muse, mutect2, varscan2
- FCHSD2 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV100238948; called by muse, mutect2, varscan2
- FDXR | c.1447C>G p.Q483E (on ENST00000293195 / NM_024417.5; = p.Q489E on NM_004110.6) | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99501331; called by muse, mutect2, varscan2
- FER1L6 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV101206129; called by muse, mutect2, varscan2
- FER1L6 | c.5487C>G p.F1829L | Missense Mutation (SNP) | VAF 64/339 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101206130; called by muse, mutect2, varscan2
- FIGN | c.2209C>T p.Q737* | Nonsense Mutation (SNP) | VAF 29/151 reads (19%) | catalogued as COSV60766386; called by muse, mutect2, varscan2
- FKBP4 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as COSV99133961; called by muse, mutect2, varscan2
- FOXC2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.27); catalogued as COSV100234295, COSV57444394; called by muse, mutect2, varscan2
- FRRS1 | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.07); catalogued as COSV99790178; called by muse, mutect2
- FSTL1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV99820921; called by muse, mutect2, varscan2
- FYB2 | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV100599730; called by muse, mutect2
- GALNT10 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 63/257 reads (25%) | catalogued as rs1306080842, COSV51729116; called by muse, mutect2, varscan2
- GBX1 | c.877C>G p.Q293E | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99881017; called by muse, mutect2, varscan2
- GC | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99910075; called by muse, mutect2, varscan2
- GDPD3 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as rs746705329, COSV99531941; called by muse, mutect2, varscan2
- GEN1 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV100438142; called by muse, mutect2, varscan2
- GIGYF1 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99309855; called by muse, mutect2, varscan2
- GLG1 | c.1640T>C p.L547S | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99216186; called by muse, mutect2, varscan2
- GNB3 | c.221C>A p.S74* | Nonsense Mutation (SNP) | VAF 49/211 reads (23%) | catalogued as COSV51835491, COSV99301569; called by muse, mutect2, varscan2
- GNB4 | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99224452; called by muse, mutect2, varscan2
- GPATCH2 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 21/162 reads (13%) | catalogued as rs1291860165, COSV100861419; called by muse, mutect2, varscan2
- GPD2 | c.1244C>G p.S415C | Missense Mutation (SNP) | VAF 67/331 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs371946081; called by muse, mutect2, varscan2
- GRHL1 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs369646093; called by muse, mutect2, varscan2
- GRM3 | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100862766; called by muse, mutect2, varscan2
- GSK3B | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 330/804 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99955398; called by muse, mutect2, varscan2
- GSKIP | c.-1-1G>A | Splice Site (SNP) | VAF 37/69 reads (54%) | catalogued as COSV101347627; called by muse, mutect2, varscan2
- GUCY2C | c.2919G>C p.K973N | Missense Mutation (SNP) | VAF 76/301 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV99664046; called by muse, mutect2, varscan2
- H2AC21 | c.56C>A p.S19* | Nonsense Mutation (SNP) | VAF 67/213 reads (31%) | catalogued as COSV100480092; called by muse, mutect2, varscan2
- H2AC6 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV100019819; called by muse, mutect2, varscan2
- H2BC21 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV100479607, COSV58611455; called by muse, mutect2, varscan2
- HCN1 | c.1907T>A p.I636N | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV100301747; called by muse, mutect2, varscan2
- HDAC9 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 101/365 reads (28%) | catalogued as COSV101287057; called by muse, mutect2, varscan2
- HDHD2 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.087); catalogued as COSV100321389; called by muse, mutect2, varscan2
- HEATR1 | c.5647G>A p.E1883K | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV100857765; called by muse, mutect2
- HECTD4 | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 55/198 reads (28%) | catalogued as COSV100296181; called by muse, mutect2, varscan2
- HEG1 | c.2177C>G p.S726C | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100230564; called by muse, mutect2, varscan2
- HERC5 | c.2470G>C p.E824Q | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV52040847, COSV99988075; called by muse, mutect2, varscan2
- HIPK1 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101060556, COSV65785807; called by muse, mutect2, varscan2
- HLA-B | c.349C>G p.H117D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs281864614, COSV101318210; called by muse, mutect2
- HLA-DOA | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs746996524, COSV100008338; called by muse, mutect2, varscan2
- HNRNPR | c.1801C>G p.Q601E | Missense Mutation (SNP) | VAF 83/388 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as COSV100164307, COSV100164684; called by muse, mutect2, varscan2
- HOXC4 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177772375, COSV100324352; called by muse, mutect2, varscan2
- HPS5 | c.1406C>G p.S469C (on ENST00000349215 / NM_181507.2; = p.S355C on NM_007216.4) | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100752356; called by muse, mutect2, varscan2
- HPSE | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100264493, COSV60985367; called by muse, mutect2, varscan2
- HRH4 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs1434620794, COSV99907992; called by muse, mutect2, varscan2
- HS3ST4 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as COSV100502539; called by muse, mutect2, varscan2
- HSCB | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV99319763; called by muse, mutect2, varscan2
- HSF5 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 53/201 reads (26%) | catalogued as COSV60419477; called by muse, mutect2, varscan2
- HSPB7 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV58890380, COSV58891124, COSV58894389; called by muse, mutect2, varscan2
- HTR2A | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.409); catalogued as COSV101096800, COSV66326834; called by muse, mutect2, varscan2
- HTR3C | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 58/389 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as rs775611831, COSV100570720; called by muse, varscan2
- HTR3C | c.924C>T p.I308= | Splice Region (SNP) | VAF 56/478 reads (12%) | catalogued as COSV100570635, COSV100570671; called by muse, varscan2
- HVCN1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99657396; called by muse, mutect2, varscan2
- HYDIN | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs867220111, COSV101143276, COSV66834912; called by muse, mutect2
- IDH3B | c.768+1G>A p.X256_splice | Splice Site (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100250280; called by muse, mutect2, varscan2
- IFNGR1 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV100880520; called by muse, mutect2, varscan2
- IFT80 | c.1484G>C p.R495P | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.157); catalogued as COSV100425059, COSV58452498; called by muse, mutect2
- IGHV4-34 | c.186G>C p.W62C | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs11546807; called by muse, mutect2, varscan2
- IGSF5 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101012125, COSV101012148; called by muse, mutect2, varscan2
- IL17RA | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV100083203, COSV100083399; called by muse, mutect2, varscan2
- IL6R | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as COSV59817418, COSV59818873; called by muse, mutect2, varscan2
- IMPG2 | c.939C>A p.F313L | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.709); catalogued as COSV99516247; called by muse, mutect2, varscan2
- INPP5D | c.2299G>C p.E767Q (on ENST00000445964 / NM_001017915.3; = p.E766Q on NM_005541.5) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV100856892, COSV64038300; called by muse, mutect2, varscan2
- INTU | c.1680C>G p.I560M | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV100081256; called by muse, mutect2
- IPO11 | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 6/175 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV100321303; called by muse, mutect2
- ITFG1 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 51/245 reads (21%) | catalogued as COSV100279110; called by muse, mutect2, varscan2
- ITGA2 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99671419; called by muse, mutect2, varscan2
- ITGAM | c.3304G>T p.E1102* (on ENST00000648685 / NM_001145808.2; = p.E1101* on NM_000632.4) | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99792974; called by muse, mutect2, varscan2
- ITSN2 | c.3745G>C p.E1249Q | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100744049, COSV61946660; called by muse, mutect2, varscan2
- JARID2 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.702); catalogued as COSV100522245; called by muse, mutect2, varscan2
- KAT14 | c.1744G>C p.D582H | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV100890105; called by muse, mutect2, varscan2
- KATNAL1 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV66062767; called by muse, mutect2, varscan2
- KCNA4 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as rs1003894683, COSV100069202; called by muse, mutect2, varscan2
- KCNB1 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 106/431 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV100870566; called by muse, mutect2, varscan2
- KCND2 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as COSV100477956; called by muse, mutect2, varscan2
- KCNH7 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV100037343, COSV59802061; called by muse, mutect2, varscan2
- KCNJ12 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV100055835; called by muse, mutect2, varscan2
- KCNJ13 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99289385; called by muse, mutect2, varscan2
- KCNJ15 | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100154352; called by muse, mutect2, varscan2
- KCTD21 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV60741313; called by muse, mutect2, varscan2
- KEAP1 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV50267115, COSV99408173; called by muse, mutect2, varscan2
- KIAA1109 | c.5210C>T p.S1737L | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99169982; called by muse, mutect2, varscan2
- KIAA1109 | c.10874G>A p.R3625K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as COSV99169991; called by muse, mutect2, varscan2
- KIAA1210 | c.4369G>A p.D1457N | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV101274360; called by muse, mutect2, varscan2
- KIAA1217 | c.5708C>T p.S1903F | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV100287112; called by muse, mutect2, varscan2
- KIF14 | c.3772G>C p.D1258H | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV100951019; called by muse, mutect2
- KIF18A | c.2522C>T p.S841L | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs369809315; called by muse, mutect2, varscan2
- KIF21A | c.3683C>G p.S1228* (on ENST00000361418 / NM_001378440.1; = p.S1215* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV100735595; called by muse, mutect2, varscan2
- KIF2B | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99276008; called by muse, mutect2, varscan2
- KLRB1 | c.260-1G>C p.X87_splice | Splice Site (SNP) | VAF 54/178 reads (30%) | catalogued as COSV99987319; called by muse, varscan2
- KPNB1 | c.2404G>C p.D802H | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99268356; called by muse, mutect2, varscan2
- KRT10 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 70/281 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as CM1511846, COSV54089222, COSV99510254; called by muse, mutect2, varscan2
- KRTCAP3 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1213041908, COSV99275238; called by muse, mutect2, varscan2
- KXD1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 121/608 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV99723712; called by muse, mutect2, varscan2
- L3MBTL3 | c.1757C>G p.S586* | Nonsense Mutation (SNP) | VAF 81/253 reads (32%) | catalogued as COSV100696339; called by muse, mutect2, varscan2
- LATS2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101231659; called by muse, mutect2, varscan2
- LCA5 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV100878352; called by muse, mutect2, varscan2
- LGALS9B | c.863G>T p.W288L (on ENST00000423676 / NM_001367292.1; = p.W287L on NM_001042685.2) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100163027; called by muse, mutect2, varscan2
- LMNB2 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100322368; called by muse, mutect2, varscan2
- LMNTD2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs148047813; called by muse, mutect2, varscan2
- LRBA | c.8591G>T p.*2864Lext*2 | Nonstop Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100842007; called by muse, mutect2, varscan2
- LRP1 | c.11864C>T p.S3955L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs1305461799, COSV99676879; called by muse, mutect2, varscan2
- LRP2 | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.278); catalogued as COSV55561737, COSV99789851; called by muse, mutect2, varscan2
- LRP3 | c.845G>A p.C282Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99472468; called by muse, mutect2, varscan2
- LRRC66 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs748782991, COSV100603059; called by muse, mutect2, varscan2
- LRRIQ1 | c.1472G>C p.R491P | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101280677; called by muse, mutect2, varscan2
- LRRN4 | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV101125512; called by muse, mutect2, varscan2
- LRTM2 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 37/126 reads (29%) | catalogued as COSV54567158, COSV99766348; called by muse, mutect2, varscan2
- MACF1 | c.10371G>C p.Q3457H | Missense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as COSV99246258; called by muse, mutect2, varscan2
- MACF1 | c.12939G>C p.K4313N (on ENST00000372915; = p.K2246N on NM_012090.5) | Missense Mutation (SNP) | VAF 33/159 reads (21%) | catalogued as COSV57152316; called by muse, mutect2, varscan2
- MAGEA11 | c.1101G>C p.K367N | Missense Mutation (SNP) | VAF 142/265 reads (54%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as COSV100290654; called by muse, varscan2
- MAP1A | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.616); catalogued as COSV100289101, COSV55808485; called by muse, mutect2, varscan2
- MAP3K10 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV99454529, COSV99454772; called by muse, mutect2, varscan2
- MAP3K13 | c.2623G>A p.D875N | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1206003203, COSV99407749; called by muse, mutect2, varscan2
- MAP3K4 | c.716C>G p.S239* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100815621; called by muse, mutect2, varscan2
- MAP3K5 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100753179; called by muse, mutect2, varscan2
- MAPK9 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100558563; called by muse, mutect2
- MBTPS1 | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.147); catalogued as COSV100597744; called by muse, mutect2, varscan2
- MCM3 | c.1998+2T>C p.X666_splice (on ENST00000229854 / NM_001366374.2; = p.X656_splice on NM_002388.6 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 69/224 reads (31%) | catalogued as COSV100009003; called by muse, mutect2, varscan2
- MCM6 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.954); catalogued as COSV99919323; called by muse, mutect2, varscan2
- ME3 | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV100661082; called by muse, mutect2, varscan2
- MED13 | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 48/167 reads (29%) | catalogued as COSV101181282; called by muse, mutect2, varscan2
- MED23 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100645314; called by muse, mutect2, varscan2
- MED27 | c.325C>G p.Q109E | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV99406804; called by muse, mutect2
- MEIS3 | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100520537; called by muse, mutect2, varscan2
- METTL21A | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777770; called by muse, mutect2, varscan2
- MFSD6L | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs764957895, COSV100319858; called by muse, mutect2, varscan2
- MFSD8 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99614642; called by muse, mutect2, varscan2
- MICAL2 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV56319799; called by muse, mutect2, varscan2
- MORC1 | c.1685T>A p.L562Q | Missense Mutation (SNP) | VAF 13/398 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99227397; called by muse, mutect2
- MORC1 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51725741, COSV51733493; called by muse, mutect2, varscan2
- MPI | c.1007C>G p.S336* | Nonsense Mutation (SNP) | VAF 69/197 reads (35%) | catalogued as COSV100086258, COSV60397772; called by muse, mutect2, varscan2
- MPP5 | c.1329G>C p.K443N | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV99907337; called by muse, mutect2, varscan2
- MPRIP | c.1781A>T p.K594M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV100506082; called by muse, mutect2, varscan2
- MRGPRX1 | c.258C>A p.S86R | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV100246127; called by muse, mutect2, varscan2
- MROH7 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.208); catalogued as COSV100273922; called by muse, mutect2, varscan2
- MTA2 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 58/176 reads (33%) | catalogued as COSV53874784, COSV99604483; called by muse, mutect2, varscan2
- MTMR4 | c.3181G>C p.E1061Q | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.878); catalogued as COSV100051351; called by muse, mutect2, varscan2
- MUC16 | c.24500C>G p.S8167* | Nonsense Mutation (SNP) | VAF 38/134 reads (28%) | catalogued as COSV101201047; called by muse, mutect2, varscan2
- MUC16 | c.22175C>T p.P7392L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1378414297, COSV101201048; called by muse, mutect2, varscan2
- MUC16 | c.18740C>G p.S6247C | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101201049; called by muse, mutect2, varscan2
- MUC17 | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 158/611 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100074704; called by muse, mutect2, varscan2
- MUC17 | c.8653G>A p.E2885K | Missense Mutation (SNP) | VAF 151/614 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV100074705, COSV60288520; called by muse, mutect2, varscan2
- MUC3A | c.8947C>T p.Q2983* | Nonsense Mutation (SNP) | VAF 16/180 reads (9%) | catalogued as rs748630783, COSV100115219; called by muse, mutect2
- MYBPC1 | c.610G>A p.E204K (on ENST00000550270 / NM_206820.2; = p.E229K on NM_002465.4) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.777); catalogued as COSV100638226; called by muse, mutect2, varscan2
- MYH10 | c.2946G>C p.K982N | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV99346069; called by muse, mutect2, varscan2
- MYH10 | c.1161G>A p.M387I | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99346073; called by muse, mutect2, varscan2
- MYH10 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 120/230 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV99346075; called by muse, mutect2, varscan2
- MYH13 | c.5322G>C p.K1774N | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52840477; called by muse, mutect2, varscan2
- MYH2 | c.4633G>C p.E1545Q | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV99820742; called by muse, mutect2, varscan2
- MYH2 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV99820743; called by muse, mutect2, varscan2
- MYO15A | c.10480C>A p.Q3494K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52752054; called by muse, mutect2, varscan2
- MYO16 | c.488T>C p.L163S | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1322487998, COSV99194417; called by muse, mutect2, varscan2
- MYO16 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs761000065, COSV99194363, COSV99194421; called by muse, mutect2, varscan2
- MYOCD | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV58504990; called by muse, mutect2, varscan2
- N4BP1 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99285509; called by muse, mutect2, varscan2
- NAP1L5 | c.279G>C p.K93N | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV52021642; called by muse, mutect2, varscan2
- NAT16 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.157); catalogued as COSV100296363; called by muse, mutect2
- NCKAP5 | c.1871G>C p.G624A | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.121); catalogued as COSV100493896; called by muse, mutect2, varscan2
- NDUFA2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52800476; called by muse, mutect2
- NEB | c.2095C>G p.Q699E | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.953); catalogued as COSV99426670; called by muse, mutect2, varscan2
- NEXMIF | c.3058G>A p.D1020N | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV50021603, COSV99281227, COSV99281597; called by muse, mutect2, varscan2
- NFIC | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100545600; called by muse, mutect2, varscan2
- NFX1 | c.3175A>T p.T1059S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV101076879; called by muse, mutect2, varscan2
- NICN1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as rs768791212, COSV99865922; called by muse, mutect2, varscan2
- NLGN1 | c.2134T>C p.C712R | Missense Mutation (SNP) | VAF 87/162 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0.395); catalogued as rs1169821645, COSV100849908; called by muse, mutect2, varscan2
- NLRP11 | c.2379C>G p.S793R | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.127); catalogued as COSV100789793; called by muse, mutect2, varscan2
- NLRP5 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1467818340, COSV101173844; called by muse, mutect2, varscan2
- NLRP7 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1377290637, COSV60171043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOM1 | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV51982494, COSV99315964; called by muse, mutect2, varscan2
- NOS2 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as COSV100569845; called by muse, mutect2, varscan2
- NOTCH1 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53049484, COSV99490937; called by mutect2, varscan2
- NPAP1 | c.3401A>G p.Y1134C | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV100275973; called by muse, mutect2, varscan2
- NRG3 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV64559314; called by muse, mutect2, varscan2
- NRXN1 | c.553C>G p.R185G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV101279430, COSV68018753; called by muse, mutect2
- NSUN2 | c.267G>C p.E89D | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.41); catalogued as COSV99243418; called by muse, mutect2, varscan2
- NTAQ1 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99783736; called by muse, mutect2, varscan2
- NUP155 | c.3398C>G p.S1133* (on ENST00000231498 / NM_153485.3; = p.S1074* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 64/318 reads (20%) | catalogued as COSV99194334; called by muse, mutect2, varscan2
- NUP160 | c.3212G>C p.R1071T | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs781128042, COSV101021613; called by muse, mutect2, varscan2
- OASL | c.534C>G p.I178M | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1565906362, COSV57478103, COSV99984478; called by muse, mutect2, varscan2
- OBI1 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99932587; called by muse, mutect2, varscan2
- ODF2 | c.393G>A p.M131I (on ENST00000434106 / NM_153433.2; = p.M107I on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV100654438, COSV100654920; called by muse, mutect2, varscan2
- OGT | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101035578; called by muse, mutect2, varscan2
- ONECUT1 | c.116C>G p.A39G | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs1318066933, COSV100009387; called by muse, mutect2, varscan2
- OR10A5 | c.749C>G p.S250C | Missense Mutation (SNP) | VAF 111/445 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV100203619; called by muse, mutect2, varscan2
- OR10G4 | c.301T>A p.Y101N | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100304939; called by muse, varscan2
- OR11H4 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV100197591, COSV59560748; called by muse, mutect2, varscan2
- OR2J3 | c.614C>G p.T205R | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV101013656; called by muse, mutect2, varscan2
- OR2T3 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 111/514 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100613377; called by muse, mutect2, varscan2
- OR6C3 | c.643T>C p.Y215H | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101110381; called by muse, mutect2, varscan2
- OR8H2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 113/409 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs1278800997, COSV100542450; called by muse, mutect2, varscan2
- OR9K2 | c.943C>G p.L315V (on ENST00000305377; = p.L293V on NM_001005243.1) | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100543895; called by muse, mutect2, varscan2
- OSBPL6 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV99508273; called by muse, mutect2, varscan2
- OSGIN2 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV99858583; called by muse, mutect2, varscan2
- OTOGL | c.4122G>C p.W1374C (on ENST00000547103; = p.W1365C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101509477; called by muse, mutect2, varscan2
- PACSIN2 | c.308C>A p.S103* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as COSV99606592; called by muse, mutect2, varscan2
- PAPPA2 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs775169340, COSV62776814, COSV62779600; called by muse, mutect2, varscan2
- PARD3 | c.1829C>G p.S610* | Nonsense Mutation (SNP) | VAF 40/158 reads (25%) | catalogued as COSV60752208; called by muse, mutect2, varscan2
- PARP14 | c.5261C>T p.S1754L | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV101506336; called by muse, mutect2, varscan2
- PARP8 | c.548T>G p.I183S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99892469; called by muse, mutect2, varscan2
- PARPBP | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1233829242, COSV59675252; called by muse, mutect2, varscan2
- PATJ | c.3706G>C p.E1236Q | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV100219905; called by muse, mutect2
- PCDHAC2 | c.2402C>G p.S801* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | catalogued as COSV53836901, COSV99154926; called by muse, mutect2, varscan2
- PCDHGA6 | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99544731; called by muse, varscan2
- PCDHGB1 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV53901777, COSV99535530; called by muse, mutect2, varscan2
- PCDHGB4 | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV99544733; called by muse, mutect2, varscan2
- PCLO | c.11759C>T p.S3920L | Missense Mutation (SNP) | VAF 121/590 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV61648472; called by muse, mutect2, varscan2
- PDE4B | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs751552605, COSV58468039; called by muse, mutect2, varscan2
- PDE5A | c.2509G>C p.E837Q | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.77); catalogued as COSV53347088, COSV53347671; called by muse, mutect2, varscan2
- PDGFRA | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 28/129 reads (22%) | catalogued as COSV57270699; called by muse, mutect2, varscan2
- PDXDC1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 50/371 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV57914361; called by muse, mutect2, varscan2
- PDZD2 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753954633, COSV56874511; called by muse, mutect2
- PDZRN4 | c.2207C>T p.S736F (on ENST00000402685 / NM_001164595.2; = p.S478F on NM_013377.4) | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868597327, COSV100115275, COSV54192745; called by muse, mutect2, varscan2
- PEAK3 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs772976788, COSV100457423; called by muse, varscan2
- PEG10 | c.517C>T p.R173C (on ENST00000482108 / NM_001040152.2; = p.R207C on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/311 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV71788097; called by muse, mutect2, varscan2
- PEX5L | c.983G>C p.G328A | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV99829645; called by muse, mutect2, varscan2
- PEX5L | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV99829648; called by muse, mutect2, varscan2
- PGM5 | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV101124015; called by muse, mutect2, varscan2
- PHACTR4 | c.1607-1G>A p.X536_splice (on ENST00000373839 / NM_001350159.2; = p.X546_splice on NM_023923.4) | Splice Site (SNP) | VAF 20/111 reads (18%) | catalogued as COSV100868448, COSV100868489; called by muse, mutect2, varscan2
- PHACTR4 | c.1740G>C p.Q580H (on ENST00000373839 / NM_001350159.2; = p.Q590H on NM_023923.4) | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1428599258, COSV100868490; called by muse, mutect2, varscan2
- PHAX | c.251G>C p.R84P | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99881319, COSV99881644; called by muse, mutect2, varscan2
- PIK3IP1 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53223925; called by muse, mutect2
- PIP5K1B | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs746948673, COSV55249164; called by muse, varscan2
- PKHD1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs755338375, COSV100584249; called by muse, mutect2, varscan2
- PKHD1L1 | c.7558G>C p.D2520H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV101006686; called by muse, mutect2, varscan2
- PLA1A | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 75/468 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs761764931, COSV56330431; called by muse, mutect2, varscan2
- PLB1 | c.158T>C p.L53S | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100579717, COSV99079980; called by muse, mutect2, varscan2
- PLEKHH1 | c.2431G>T p.G811* | Nonsense Mutation (SNP) | VAF 52/95 reads (55%) | catalogued as COSV100233429; called by muse, mutect2, varscan2
- PLOD2 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV51461990, COSV99283165; called by muse, mutect2, varscan2
- PLP1 | c.391C>G p.Q131E | Missense Mutation (SNP) | VAF 94/189 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100393525; called by muse, mutect2, varscan2
- PLSCR2 | c.473G>A p.R158Q (on ENST00000497985 / NM_001199978.1; = p.R85Q on NM_020359.2) | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as rs771213218, COSV99072490; called by muse, mutect2, varscan2
- PLXNA3 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.763); catalogued as COSV100860193, COSV63753730, COSV63753840; called by muse, mutect2, varscan2
- PNKP | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99681978; called by muse, mutect2, varscan2
- PNLIPRP2 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.287); catalogued as COSV100077920; called by muse, mutect2, varscan2
- POLR2D | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 57/280 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.796); catalogued as COSV99761086; called by muse, mutect2, varscan2
- POM121L12 | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs775680595, COSV101374964, COSV68692532; called by muse, mutect2
- POTEA | c.1160C>T p.P387L (on ENST00000519951 / NM_001005365.2; = p.P341L on NM_001002920.1) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs774111846; called by muse, mutect2, varscan2
- POU3F2 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100099413, COSV100099524, COSV60409436; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 61/294 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as rs752291134, COSV53450791; called by muse, mutect2, varscan2
- PPL | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as rs1461284259, COSV100631004; called by muse, mutect2, varscan2
- PPL | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV100631005; called by muse, mutect2, varscan2
- PPM1E | c.1971C>G p.F657L | Missense Mutation (SNP) | VAF 97/411 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs369185588; called by muse, mutect2, varscan2
- PPP1R12A | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as COSV99700724; called by muse, mutect2, varscan2
- PPP1R21 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 32/150 reads (21%) | catalogued as COSV99682481; called by muse, mutect2, varscan2
- PPP1R9A | c.2479C>G p.Q827E | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as COSV99197599; called by muse, mutect2, varscan2
- PPP4R1 | c.1522G>T p.E508* (on ENST00000400556 / NM_001042388.3; = p.E491* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 58/252 reads (23%) | catalogued as COSV99553870; called by muse, mutect2, varscan2
- PRAMEF1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 99/435 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.423); catalogued as COSV100180027; called by muse, mutect2, varscan2
- PRAMEF12 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 30/120 reads (25%) | catalogued as rs757917825, COSV100743545; called by muse, mutect2, varscan2
- PRDM11 | c.678G>C p.E226D (on ENST00000530656 / NM_001359633.1; = p.E192D on NM_001256695.1) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.109); catalogued as COSV99771033; called by muse, mutect2, varscan2
- PRKAB1 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs750394660, COSV99982461; called by muse, mutect2, varscan2
- PRKDC | c.5708C>T p.S1903L | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); catalogued as rs1369832974, COSV100042333, COSV58049471; called by muse, mutect2, varscan2
- PRKRIP1 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100700355; called by muse, mutect2, varscan2
- PRPF8 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV100517805; called by muse, mutect2, varscan2
- PSG5 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 114/499 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV100743067; called by muse, mutect2, varscan2
- PTEN | c.42G>T p.R14S | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as CD110175, COSV64299295; called by muse, mutect2, varscan2
- PTK2 | c.840C>G p.I280M | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100570971; called by muse, mutect2, varscan2
- PUF60 | c.1234C>G p.L412V (on ENST00000526683 / NM_001362896.2; = p.L395V on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV57590295; called by muse, mutect2, varscan2
- PXDN | c.3754G>C p.E1252Q | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99414617; called by muse, mutect2, varscan2
- RABGEF1 | c.439G>A p.E147K (on ENST00000439720 / NM_001287061.2; = p.E134K on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99535056; called by muse, mutect2, varscan2
- RAD23A | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV100330727, COSV100330991; called by muse, mutect2, varscan2
- RASL11B | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99954520; called by muse, mutect2, varscan2
- RBBP8 | c.2414G>C p.R805T | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100507592; called by muse, mutect2, varscan2
- RBM5 | c.1181C>G p.S394* | Nonsense Mutation (SNP) | VAF 65/157 reads (41%) | catalogued as COSV100762453, COSV100762552; called by muse, mutect2, varscan2
- RBMXL2 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs778641094, COSV60982259; called by muse, mutect2, varscan2
- RC3H2 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100106870; called by muse, mutect2, varscan2
- RFX6 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 45/233 reads (19%) | catalogued as COSV100264151; called by muse, mutect2, varscan2
- RLF | c.3245C>G p.S1082* | Nonsense Mutation (SNP) | VAF 48/241 reads (20%) | catalogued as COSV101035641; called by muse, mutect2, varscan2
- RNF17 | c.4559C>A p.S1520* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV99694140; called by muse, varscan2
- RNF213 | c.12454G>A p.E4152K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100301274; called by muse, mutect2, varscan2
- RNH1 | c.149C>G p.S50C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100596817; called by muse, mutect2, varscan2
- ROCK1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101296591; called by muse, mutect2, varscan2
- ROR2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.202); catalogued as rs761854477, COSV65218280; called by muse, mutect2
- RP1 | c.1663C>G p.Q555E | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV99608529; called by muse, mutect2, varscan2
- RP1L1 | c.3423C>G p.F1141L | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV101223530; called by muse, mutect2, varscan2
- RRM1 | c.471G>T p.L157F | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.304); catalogued as COSV100331431; called by muse, mutect2, varscan2
- RSF1 | c.3995C>G p.S1332* | Nonsense Mutation (SNP) | VAF 66/229 reads (29%) | catalogued as COSV100407746; called by muse, mutect2, varscan2
- RTL3 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100330025; called by muse, mutect2, varscan2
- RUBCN | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs747666746, COSV99584859; called by muse, mutect2, varscan2
- RXFP1 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs368105232, COSV57055308; called by muse, mutect2, varscan2
- SAP30L | c.522G>C p.Q174H | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99770467; called by muse, mutect2, varscan2
- SCN1A | c.5154C>G p.F1718L (on ENST00000303395 / NM_001202435.3; = p.F1707L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100321630; called by muse, mutect2, varscan2
- SDCCAG8 | c.1222-1G>A p.X408_splice | Splice Site (SNP) | VAF 10/125 reads (8%) | catalogued as COSV100654512; called by muse, mutect2
- SEMA5A | c.3029C>A p.S1010* | Nonsense Mutation (SNP) | VAF 75/336 reads (22%) | catalogued as COSV101228644; called by muse, mutect2, varscan2
- SEMA5B | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV99532949; called by muse, mutect2, varscan2
- SEMG2 | c.261G>C p.L87F | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV101034210; called by muse, mutect2, varscan2
- SFI1 | c.3626T>A p.V1209E (on ENST00000400288 / NM_001007467.3; = p.V1178E on NM_014775.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99837362; called by muse, varscan2
- SFMBT2 | c.1236G>A p.M412I | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100739455; called by muse, mutect2, varscan2
- SH2B3 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780842512, COSV57986402; called by muse, mutect2, varscan2
- SHB | c.1026G>C p.W342C | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100891868; called by muse, mutect2, varscan2
- SHOX2 | c.448G>A p.E150K (on ENST00000441443 / NM_006884.3; = p.E174K on NM_003030.4) | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101273818, COSV67464718; called by muse, mutect2, varscan2
- SHROOM2 | c.3556C>G p.P1186A | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101098978, COSV66610798; called by muse, mutect2, varscan2
- SIDT1 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 144/328 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs990449684, COSV53504467; called by muse, mutect2, varscan2
- SIK3 | c.2464C>T p.Q822* (on ENST00000445177 / NM_001366686.2; = p.Q780* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/146 reads (22%) | catalogued as COSV99408640; called by muse, mutect2, varscan2
- SKA3 | c.1139C>G p.S380* | Nonsense Mutation (SNP) | VAF 33/199 reads (17%) | catalogued as rs1219387142, COSV100006486; called by muse, mutect2, varscan2
- SKIV2L | c.2039C>G p.S680C | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100514816; called by muse, mutect2, varscan2
- SLC22A10 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100235972, COSV60421190, COSV60421696; called by muse, mutect2
- SLC22A11 | c.377C>G p.S126C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100102603; called by muse, mutect2, varscan2
- SLC22A7 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101000804, COSV101000862; called by muse, mutect2, varscan2
- SLC26A5 | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs778471150, COSV100099948; called by muse, mutect2, varscan2
- SLC30A3 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV51987876, COSV99273824; called by muse, mutect2, varscan2
- SLC30A8 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1419208998, COSV101438736; called by muse, mutect2, varscan2
- SLC46A3 | c.927G>C p.L309F | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV99906333, COSV99906487; called by muse, mutect2, varscan2
- SLC46A3 | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99906490; called by muse, mutect2, varscan2
- SLC4A8 | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV100177385, COSV60658554; called by muse, mutect2, varscan2
- SLC5A12 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV101237742; called by muse, mutect2, varscan2
- SLC6A5 | c.1845C>G p.I615M | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100117090; called by muse, mutect2, varscan2
- SLCO1B3 | c.1771T>G p.F591V | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV99682072; called by muse, mutect2, varscan2
- SLCO2B1 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 114/361 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as COSV56940102; called by muse, mutect2, varscan2
- SLITRK5 | c.2025C>G p.I675M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100281094, COSV61523904; called by muse, mutect2, varscan2
- SMAD4 | c.297G>C p.W99C | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747506, COSV61687574; called by muse, mutect2, varscan2
- SMTNL2 | c.833C>T p.S278L (on ENST00000389313 / NM_001114974.2; = p.S134L on NM_198501.3) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs1046651219, COSV100130875; called by muse, varscan2
- SNRPN | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 90/409 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100578508; called by muse, mutect2, varscan2
- SOX30 | c.526G>C p.G176R | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.046); catalogued as COSV53938101, COSV99398701; called by muse, mutect2, varscan2
- SPATA31D1 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100783003; called by muse, mutect2, varscan2
- SPATS1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1221707835, COSV99913608; called by muse, mutect2, varscan2
- SPDL1 | c.486G>C p.E162D | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV54669352; called by muse, mutect2, varscan2
- SPEG | c.704G>C p.R235P | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV100405385; called by muse, mutect2, varscan2
- SPEM2 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.381); catalogued as COSV100424447; called by muse, mutect2, varscan2
- SPG11 | c.4941G>C p.Q1647H | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV99967858, COSV99969334; called by muse, mutect2, varscan2
- SPICE1 | c.2046C>G p.I682M | Missense Mutation (SNP) | VAF 118/279 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as rs1429143197, COSV99871669; called by muse, mutect2, varscan2
- SPRYD7 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100709868; called by muse, mutect2, varscan2
- SPTA1 | c.3411C>G p.I1137M | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.349); catalogued as COSV63757090; called by muse, mutect2, varscan2
- SPTY2D1 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 78/379 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV100311802, COSV100311872; called by muse, mutect2, varscan2
- SRCAP | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | catalogued as COSV99351069; called by muse, mutect2, varscan2
- SRGAP3 | c.1486C>T p.L496F | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0.205); catalogued as COSV64534317; called by muse, mutect2, varscan2
- SRRM1 | c.2074C>G p.Q692E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100105037; called by muse, mutect2, varscan2
- SRRM2 | c.3634G>C p.E1212Q | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.203); catalogued as COSV100071325; called by muse, mutect2, varscan2
- SSTR1 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as COSV99943090; called by muse, mutect2, varscan2
- SSTR3 | c.411G>C p.M137I | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100142869; called by muse, mutect2, varscan2
- STAR | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs1307317629, COSV99379160; called by muse, mutect2, varscan2
- STARD4 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375744963; called by muse, mutect2, varscan2
- STK36 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs180843126, COSV55306462; called by muse, mutect2, varscan2
- STON1 | c.1424C>G p.S475* | Nonsense Mutation (SNP) | VAF 42/190 reads (22%) | catalogued as COSV100562157; called by muse, mutect2, varscan2
- STOX1 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV100058168; called by muse, mutect2, varscan2
- SUCO | c.982-1G>C p.X328_splice | Splice Site (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99743528; called by muse, mutect2, varscan2
- SUCO | c.1956G>C p.L652F | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV99743532; called by muse, mutect2, varscan2
- SULF1 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV99484061; called by muse, mutect2, varscan2
- SUPT6H | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV100112703; called by muse, mutect2, varscan2
- SVEP1 | c.9037G>C p.E3013Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99929577; called by muse, mutect2, varscan2
- SYNE2 | c.18172G>C p.E6058Q | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751813329, COSV100648344, COSV59944886; called by muse, mutect2, varscan2
- SYT10 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 86/338 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV57342541; called by muse, mutect2, varscan2
- SZT2 | c.7558C>T p.P2520S (on ENST00000634258 / NM_001365999.1; = p.P2463S on NM_015284.4) | Missense Mutation (SNP) | VAF 102/512 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.187); catalogued as COSV100987587; called by muse, mutect2, varscan2
- SZT2 | c.8436G>A p.M2812I (on ENST00000634258 / NM_001365999.1; = p.M2755I on NM_015284.4) | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.663); catalogued as rs772705966, COSV100987588; called by muse, mutect2, varscan2
- TAOK1 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 8/225 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99914584; called by muse, mutect2
- TBCD | c.2682C>G p.I894M | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV100833648; called by muse, mutect2, varscan2
- TBX20 | c.1199C>A p.S400* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV101282409; called by muse, mutect2, varscan2
- TBX5 | c.243-2A>C p.X81_splice | Splice Site (SNP) | VAF 45/183 reads (25%) | catalogued as CS054233, COSV100091913; called by muse, mutect2, varscan2
- TBXAS1 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV99695840; called by muse, mutect2, varscan2
- TCAF1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63518946; called by muse, mutect2, varscan2
- TCEAL2 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV100216377; called by muse, mutect2, varscan2
- TENM2 | c.3313G>T p.V1105F (on ENST00000518659 / NM_001122679.2; = p.V873F on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101319365; called by muse, varscan2
- TFAP2B | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 107/300 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99540698; called by muse, mutect2, varscan2
- TFAP4 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV99200091; called by muse, mutect2, varscan2
- THAP5 | c.949G>C p.V317L (on ENST00000415914 / NM_001130475.3; = p.V275L on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV100542882; called by muse, mutect2, varscan2
- THBS4 | c.1713T>A p.D571E | Missense Mutation (SNP) | VAF 67/312 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100644394; called by muse, mutect2, varscan2
- THSD4 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.635); catalogued as COSV99966686; called by muse, mutect2, varscan2
- TIAM1 | c.3933G>C p.K1311N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99738140; called by muse, mutect2, varscan2
- TIMD4 | c.160T>A p.W54R | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99192839; called by muse, mutect2, varscan2
- TIPRL | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100893323; called by muse, mutect2, varscan2
- TJP3 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV99516400; called by muse, mutect2, varscan2
- TLE1 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100918961; called by muse, mutect2, varscan2
- TLE4 | c.1204C>G p.Q402E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV99512475, COSV99512904; called by muse, mutect2, varscan2
- TLNRD1 | c.1079C>G p.S360C | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99146145; called by muse, mutect2
- TMCC2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.749); catalogued as rs745631951, COSV100405605; called by muse, mutect2, varscan2
- TMED7 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs935663989, COSV99143404; called by muse, mutect2, varscan2
- TMEM132B | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs1384211745, COSV54750164; called by muse, mutect2, varscan2
- TMEM260 | c.320C>G p.S107* | Nonsense Mutation (SNP) | VAF 148/289 reads (51%) | catalogued as COSV99840588; called by muse, mutect2, varscan2
- TMEM67 | c.182C>G p.S61W | Missense Mutation (SNP) | VAF 69/364 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs746906232, COSV100019749; called by muse, mutect2, varscan2
- TMPRSS5 | c.876G>C p.E292D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100244814; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as COSV100836201; called by muse, mutect2, varscan2
- TP53BP1 | c.5912C>T p.S1971F | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99539358; called by muse, mutect2, varscan2
- TPK1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1267015614, COSV100766029, COSV63650034; called by muse, mutect2, varscan2
- TRAF7 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs771191963, COSV58218499, COSV58219483; called by muse, mutect2, varscan2
- TRIM23 | c.251C>G p.S84* | Nonsense Mutation (SNP) | VAF 49/151 reads (32%) | catalogued as COSV99140170; called by muse, mutect2, varscan2
- TRIT1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as rs1297238576, COSV100381679; called by muse, mutect2, varscan2
- TRPA1 | c.2869-1G>C p.X957_splice | Splice Site (SNP) | VAF 23/109 reads (21%) | catalogued as COSV100084952; called by muse, mutect2, varscan2
- TRPM2 | c.2959G>T p.D987Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100309208, COSV55966200; called by muse, mutect2, varscan2
- TSC22D1 | c.3187C>A p.Q1063K (on ENST00000458659 / NM_183422.4; = p.Q134K on NM_006022.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV99817967; called by muse, varscan2
- TSC22D1 | c.621G>C p.Q207H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as rs371261364, COSV71775262; called by muse, mutect2, varscan2
- TTC29 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100284376, COSV57281959; called by muse, mutect2, varscan2
- TTC30A | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100826223; called by muse, mutect2, varscan2
- TTC7B | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 107/181 reads (59%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as COSV60624880, COSV60630532; called by muse, mutect2, varscan2
- TTN | c.51808G>A p.D17270N (on ENST00000591111; = p.D9846N on NM_003319.4) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | PolyPhen probably damaging (0.998); catalogued as COSV60363220; called by muse, varscan2
- TTN | c.39961G>A p.E13321K (on ENST00000591111; = p.E5897K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | PolyPhen probably damaging (0.994); catalogued as COSV100625740, COSV60215313; called by muse, mutect2, varscan2
- TTN | c.6673G>C p.D2225H (on ENST00000591111; = p.D2179H on NM_003319.4) | Missense Mutation (SNP) | VAF 31/136 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV100625745; called by muse, mutect2, varscan2
- TTN | c.2368C>T p.Q790* (on ENST00000591111; = p.Q744* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as COSV100625749; called by muse, mutect2, varscan2
- TUT4 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV57118979, COSV99932694; called by muse, mutect2, varscan2
- UBAP2L | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV55184962; called by muse, mutect2
- UBE3C | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV100780057; called by muse, mutect2, varscan2
- UBR5 | c.6507C>T p.F2169= | Splice Region (SNP) | VAF 37/171 reads (22%) | catalogued as COSV55297253, COSV99642021; called by muse, mutect2, varscan2
- UBR5 | c.2614G>C p.E872Q | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV99642022; called by muse, mutect2, varscan2
- UBXN1 | c.809C>G p.S270* | Nonsense Mutation (SNP) | VAF 76/321 reads (24%) | catalogued as COSV99583370; called by muse, mutect2, varscan2
- UGGT2 | c.4448G>C p.R1483T | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948846; called by muse, mutect2, varscan2
- UGT2A1 | c.639C>G p.F213L | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV99684795; called by muse, mutect2, varscan2
- UNC79 | c.4324G>A p.A1442T (on ENST00000393151 / NM_001346218.2; = p.A1265T on NM_020818.5) | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as COSV56372746, COSV56382665, COSV99829498; called by muse, mutect2, varscan2
- USP19 | c.2725C>A p.Q909K | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT tolerated (0.9); PolyPhen benign (0.038); catalogued as COSV100026428; called by muse, mutect2, varscan2
- USP44 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99311994; called by muse, mutect2, varscan2
- UTP20 | c.7080G>C p.E2360D | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99882328; called by muse, mutect2, varscan2
- UTRN | c.3958G>C p.D1320H | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV100840339; called by muse, mutect2, varscan2
- VAT1L | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100214025; called by muse, mutect2, varscan2
- VCPIP1 | c.2990C>G p.S997* | Nonsense Mutation (SNP) | VAF 81/377 reads (21%) | catalogued as COSV100125752; called by muse, mutect2, varscan2
- VPS13A | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.28); catalogued as COSV100653321; called by muse, mutect2, varscan2
- VPS13B | c.5448G>T p.Q1816H | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs534024412, COSV100663115; called by muse, mutect2, varscan2
- VPS41 | c.1960G>C p.E654Q | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as COSV100054196; called by muse, mutect2, varscan2
- VSIG2 | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.751); catalogued as COSV99423440; called by muse, mutect2, varscan2
- WARS2 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.03); catalogued as COSV99346694; called by muse, mutect2, varscan2
- WASHC3 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99527604; called by muse, mutect2
- WDFY3 | c.8800C>G p.L2934V | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99885119; called by muse, varscan2
- WDFY3 | c.8736C>G p.D2912E | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99885121; called by muse, varscan2
- WDR19 | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV99975843; called by muse, mutect2, varscan2
- WFIKKN1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs762221711, COSV99937931; called by muse, mutect2, varscan2
- WNK2 | c.5666C>T p.S1889L (on ENST00000297954 / NM_001282394.1; = p.S1852L on NM_006648.3) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs568296567, COSV99944114; called by muse, mutect2, varscan2
- WNK3 | c.1188C>G p.I396M | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100671960; called by muse, mutect2, varscan2
- WNK4 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as COSV99891216; called by muse, mutect2, varscan2
- WNK4 | c.3729G>A p.M1243I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV99891224; called by muse, mutect2, varscan2
- WSB2 | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); catalogued as COSV99969991; called by muse, mutect2
- WWC1 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV54651442, COSV99515717; called by muse, mutect2, varscan2
- XPOT | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 66/225 reads (29%) | catalogued as COSV100225711; called by muse, mutect2, varscan2
- YIPF5 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99188358; called by muse, mutect2, varscan2
- ZBED9 | c.2183G>C p.R728T | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV101509361; called by muse, mutect2, varscan2
- ZFP36L2 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV56697423, COSV56700013; called by muse, mutect2, varscan2
- ZFPL1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 133/486 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.26); catalogued as COSV99297994; called by muse, mutect2, varscan2
- ZHX3 | c.1525C>G p.L509V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777164408, COSV100476585; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as COSV100048492, COSV60156748; called by muse, mutect2, varscan2
- ZMAT1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 84/143 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100858901, COSV65658716; called by muse, mutect2, varscan2
- ZNF134 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101270768; called by muse, mutect2, varscan2
- ZNF148 | c.2057C>G p.S686* | Nonsense Mutation (SNP) | VAF 75/366 reads (20%) | catalogued as COSV100642164; called by muse, mutect2, varscan2
- ZNF22 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 58/127 reads (46%) | catalogued as rs898967621, COSV53584050; called by muse, mutect2, varscan2
- ZNF232 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV51502355; called by muse, mutect2, varscan2
- ZNF250 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV99481025; called by muse, mutect2, varscan2
- ZNF282 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs760179364, COSV100021841; called by muse, mutect2, varscan2
- ZNF329 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63772636; called by muse, mutect2, varscan2
- ZNF331 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV53476184, COSV99467801; called by muse, mutect2, varscan2
- ZNF358 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99900791; called by muse, mutect2, varscan2
- ZNF415 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54704912, COSV99701481; called by muse, mutect2, varscan2
- ZNF462 | c.4869G>A p.M1623I | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs774371730, COSV99472997; called by muse, mutect2, varscan2
- ZNF471 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV100340790; called by muse, mutect2, varscan2
- ZNF471 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100340792; called by muse, mutect2, varscan2
- ZNF483 | c.1208C>G p.S403* | Nonsense Mutation (SNP) | VAF 76/245 reads (31%) | catalogued as COSV100493082; called by muse, mutect2, varscan2
- ZNF534 | c.379C>T p.Q127* (on ENST00000332323 / NM_001143939.3; = p.Q114* on NM_001143938.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as rs1383901484, COSV99990075; called by muse, mutect2, varscan2
- ZNF536 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100835688; called by muse, mutect2, varscan2
- ZNF551 | c.1726C>G p.Q576E | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as COSV99990258; called by muse, mutect2, varscan2
- ZNF566 | c.542G>C p.R181T | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV67573667; called by muse, mutect2, varscan2
- ZNF585A | c.1126C>A p.H376N (on ENST00000292841 / NM_001288800.2; = p.H321N on NM_152655.3) | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99493468; called by muse, mutect2, varscan2
- ZNF587 | c.446G>C p.R149T | Missense Mutation (SNP) | VAF 55/388 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.486); catalogued as COSV100299628; called by muse, mutect2, varscan2
- ZNF594 | c.1166C>G p.S389* | Nonsense Mutation (SNP) | VAF 167/591 reads (28%) | catalogued as COSV101280546; called by muse, mutect2, varscan2
- ZNF594 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.304); catalogued as rs781589373, COSV101280547; called by muse, mutect2
- ZNF607 | c.1798C>A p.H600N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV100777943; called by muse, mutect2, varscan2
- ZNF683 | c.1450G>C p.E484Q (on ENST00000403843; = p.E464Q on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV100853734; called by muse, mutect2, varscan2
- ZNF684 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV101016119; called by muse, mutect2, varscan2
- ZNF746 | c.1706C>T p.T569I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100502554; called by muse, mutect2, varscan2
- ZNF829 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 24/134 reads (18%) | catalogued as rs778613616, COSV101199704; called by muse, mutect2, varscan2
- ZNF83 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 42/185 reads (23%) | catalogued as rs748239807, COSV99991519; called by muse, varscan2
- ZNF836 | c.1210C>T p.H404Y | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100441168; called by muse, mutect2
- ZSCAN31 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 138/360 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV100717105; called by muse, mutect2, varscan2
- ACACA | c.2891G>A p.S964N | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ACSF2 | c.1528_1532del p.K510Yfs*7 | Frame Shift Del (DEL) | VAF 42/189 reads (22%) | called by mutect2, pindel, varscan2
- BCL3 | c.1309dup p.V437Gfs*30 | Frame Shift Ins (INS) | VAF 68/332 reads (20%) | called by mutect2, pindel, varscan2
- DDX3X | c.103+1dup | Frame Shift Ins (INS) | VAF 38/98 reads (39%) | called by mutect2, pindel, varscan2
- DPAGT1 | c.546dup p.A183Cfs*9 | Frame Shift Ins (INS) | VAF 32/157 reads (20%) | called by mutect2, pindel, varscan2
- EPPK1 | c.4987_4993del p.L1663Rfs*50 | Frame Shift Del (DEL) | VAF 23/175 reads (13%) | called by mutect2, pindel, varscan2
- HEPH | c.3091del p.V1031Lfs*13 (on ENST00000343002; = p.V764Lfs*13 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 33/84 reads (39%) | called by mutect2, pindel, varscan2
- LHFPL6 | c.373C>G p.Q125E | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2
- MROH1 | c.3502G>C p.E1168Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- MTMR3 | c.1879C>G p.L627V | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2
- PLXNA1 | c.3368del p.P1123Rfs*41 | Frame Shift Del (DEL) | VAF 65/228 reads (29%) | called by mutect2, pindel, varscan2
- TMEM132E | c.1630del p.V544Wfs*31 (on ENST00000321639; = p.V634Wfs*31 on NM_001304438.2) | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- USH2A | c.1032del p.F344Lfs*26 | Frame Shift Del (DEL) | VAF 41/162 reads (25%) | called by mutect2, pindel, varscan2
- VSIG4 | c.1184del p.G395Afs*17 | Frame Shift Del (DEL) | VAF 30/65 reads (46%) | called by mutect2, pindel, varscan2
- A2M | c.3642C>G p.L1214= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100588907; called by muse, mutect2, varscan2
- AADACL4 | c.1223G>A p.*408= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as COSV100879486; called by muse, mutect2, varscan2
- ABCF2 | c.942G>A p.V314= | Silent (SNP) | VAF 81/313 reads (26%) | catalogued as COSV99734780; called by muse, mutect2, varscan2
- ACADSB | c.498C>G p.L166= | Silent (SNP) | VAF 60/113 reads (53%) | catalogued as COSV100715286; called by muse, mutect2, varscan2
- ACADVL | c.1911C>T p.I637= | Silent (SNP) | VAF 45/201 reads (22%) | catalogued as COSV99138775; called by muse, mutect2, varscan2
- ACSM2B | c.333G>C p.V111= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100313042; called by muse, mutect2, varscan2
- ADAM15 | c.2421G>A p.P807= (on ENST00000356955 / NM_207197.3; = p.P782= on NM_207195.3) | Silent (SNP) | VAF 104/258 reads (40%) | catalogued as rs759494843, COSV55126093; called by muse, mutect2, varscan2
- ADAMTS5 | c.174C>T p.P58= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99538172; called by muse, mutect2
- ADCK1 | c.771G>A p.T257= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as rs768606266, COSV53087876; called by muse, mutect2, varscan2
- ALAS1 | c.1014C>T p.N338= | Silent (SNP) | VAF 92/217 reads (42%) | catalogued as COSV100050455; called by muse, mutect2, varscan2
- ANGEL1 | c.1560C>T p.I520= | Silent (SNP) | VAF 94/164 reads (57%) | catalogued as rs1470133203, COSV51875112; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1872G>C p.V624= | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as COSV100628634; called by muse, mutect2, varscan2
- AP1M2 | c.879C>T p.I293= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1381082639, COSV99140982; called by muse, mutect2, varscan2
- ARC | c.327C>G p.V109= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100751764, COSV63078569; called by muse, mutect2, varscan2
- ASB1 | c.159C>T p.L53= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV99223410; called by muse, mutect2, varscan2
- ATP2C1 | c.1158G>C p.V386= | Silent (SNP) | VAF 114/682 reads (17%) | catalogued as COSV100146933; called by muse, mutect2, varscan2
- ATXN7 | c.2586G>A p.V862= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV99895151; called by muse, mutect2
- BFAR | c.894C>T p.F298= | Silent (SNP) | VAF 83/314 reads (26%) | catalogued as COSV99902400; called by muse, mutect2, varscan2
- C16orf71 | c.1443C>G p.L481= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99556506; called by muse, mutect2, varscan2
- C1orf94 | c.1380C>G p.L460= (on ENST00000488417 / NM_001134734.2; = p.L270= on NM_032884.5) | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV64914225; called by muse, mutect2, varscan2
- CACNA1G | c.735G>A p.E245= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100662367; called by muse, mutect2, varscan2
- CALB2 | c.585G>A p.L195= | Silent (SNP) | VAF 54/196 reads (28%) | catalogued as rs143688092, COSV100226100; called by muse, varscan2
- CALHM2 | c.27C>T p.F9= | Silent (SNP) | VAF 73/162 reads (45%) | catalogued as COSV99588779; called by muse, mutect2, varscan2
- CAMSAP1 | c.1116C>T p.F372= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs546949363, COSV56721170; called by muse, mutect2, varscan2
- CAPN10 | c.945C>G p.L315= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as COSV99550503; called by muse, mutect2, varscan2
- CAPSL | c.399C>T p.I133= | Silent (SNP) | VAF 65/287 reads (23%) | catalogued as rs1428840754, COSV68439230; called by muse, mutect2, varscan2
- CARD10 | c.2667C>T p.S889= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV99325283; called by muse, mutect2, varscan2
- CD1C | c.876C>T p.I292= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100939433; called by muse, mutect2, varscan2
- CDHR3 | c.456C>T p.F152= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100488757; called by muse, mutect2, varscan2
- CDK13 | c.4236C>T p.L1412= | Silent (SNP) | VAF 87/330 reads (26%) | catalogued as rs752706166, COSV99475969; called by muse, mutect2, varscan2
- CELA3A | c.117C>T p.S39= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as COSV99266679; called by muse, mutect2, varscan2
- CES5A | c.681G>A p.A227= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs774007778, COSV99307944; called by muse, mutect2, varscan2
- CETP | c.141G>C p.V47= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV99570045, COSV99570287; called by muse, mutect2, varscan2
- CFTR | c.2835G>A p.S945= | Silent (SNP) | VAF 51/172 reads (30%) | catalogued as rs193922513, COSV50081176; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- CILP | c.411C>T p.F137= | Silent (SNP) | VAF 75/260 reads (29%) | catalogued as COSV99973823; called by muse, mutect2, varscan2
- CKAP5 | c.2313G>C p.V771= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100371280; called by muse, mutect2, varscan2
- CLDN23 | c.387C>A p.L129= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV101093172; called by muse, mutect2, varscan2
- CMYA5 | c.10203C>T p.I3401= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as COSV71408149; called by muse, mutect2, varscan2
- CNTN5 | c.615C>T p.V205= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1393652184, COSV99680212; called by muse, mutect2, varscan2
- COL11A2 | c.4101G>C p.L1367= (on ENST00000341947 / NM_080680.3; = p.L1260= on NM_080679.2) | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as COSV100554415; called by muse, mutect2, varscan2
- COL4A3 | c.1197G>C p.L399= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV101170496, COSV67422113; called by muse, mutect2, varscan2
- CPT1A | c.342G>C p.L114= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV99681523; called by muse, mutect2, varscan2
- CSMD3 | c.5424G>A p.Q1808= (on ENST00000297405 / NM_001363185.1; = p.Q1704= on NM_052900.3) | Silent (SNP) | VAF 74/264 reads (28%) | catalogued as COSV99844327; called by muse, mutect2, varscan2
- CSRNP1 | c.1491C>G p.L497= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV99827063; called by muse, mutect2, varscan2
- CTBP2 | c.1035C>T p.I345= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100456823; called by muse, mutect2, varscan2
- CTSD | c.1218C>T p.F406= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as rs199603943; called by muse, mutect2, varscan2
- CUL7 | c.2070G>A p.L690= | Silent (SNP) | VAF 48/242 reads (20%) | catalogued as COSV99539127; called by muse, mutect2, varscan2
- CYFIP1 | c.2967G>A p.L989= | Silent (SNP) | VAF 59/205 reads (29%) | catalogued as rs1420412437, COSV100488690; called by muse, varscan2
- DACT3 | c.1869C>G p.L623= | Silent (SNP) | VAF 120/536 reads (22%) | catalogued as COSV100340263, COSV100340486; called by muse, mutect2, varscan2
- DCDC1 | c.861G>A p.K287= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV100664027; called by muse, mutect2, varscan2
- DEAF1 | c.342C>T p.F114= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs867499392, COSV100102295; called by muse, varscan2
- DGAT2L6 | c.354C>A p.I118= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV100284115, COSV60718494; called by muse, mutect2, varscan2
- DHRS12 | c.549G>A p.L183= (on ENST00000444610 / NM_001377930.1; = p.L134= on NM_024705.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as COSV99523952; called by muse, mutect2, varscan2
- DHRS7 | c.573C>T p.I191= | Silent (SNP) | VAF 112/210 reads (53%) | catalogued as COSV99381721; called by muse, mutect2, varscan2
- DHTKD1 | c.2601G>A p.Q867= | Silent (SNP) | VAF 88/217 reads (41%) | catalogued as COSV99536824; called by muse, varscan2
- DHX29 | c.2763A>T p.P921= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV99287623; called by muse, mutect2, varscan2
- DNAAF5 | c.1131G>A p.V377= | Silent (SNP) | VAF 73/260 reads (28%) | catalogued as rs151119269, COSV99860194; called by muse, mutect2, varscan2
- DNAH9 | c.5781C>T p.I1927= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV52347118; called by muse, mutect2, varscan2
- DNAI4 | c.762C>T p.V254= | Silent (SNP) | VAF 54/216 reads (25%) | catalogued as COSV100925239; called by muse, mutect2, varscan2
- DNHD1 | c.11235G>C p.L3745= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99600776; called by muse, mutect2, varscan2
- DRD5 | c.582A>G p.P194= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV100431984; called by muse, mutect2, varscan2
- DTWD2 | c.858C>G p.L286= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV100407111; called by muse, mutect2, varscan2
- DYM | c.351C>T p.F117= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV99493923; called by muse, mutect2, varscan2
- EBNA1BP2 | c.444G>A p.Q148= | Silent (SNP) | VAF 79/414 reads (19%) | catalogued as COSV99356075; called by muse, mutect2, varscan2
- ECHDC2 | c.321G>C p.V107= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV100597722; called by muse, mutect2, varscan2
- EPB41L3 | c.2097C>T p.A699= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs140128908, COSV59465390; called by muse, mutect2, varscan2
- ERBB3 | c.3606G>C p.R1202= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as COSV99917624; called by muse, mutect2, varscan2
- ERBB4 | c.1776A>G p.K592= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV99630516; called by muse, mutect2, varscan2
- FAM151A | c.36C>G p.V12= | Silent (SNP) | VAF 59/308 reads (19%) | catalogued as rs1557676085, COSV100157073; called by muse, mutect2, varscan2
- FAT4 | c.5796C>T p.F1932= | Silent (SNP) | VAF 50/201 reads (25%) | catalogued as COSV100628248, COSV100629757; called by muse, mutect2, varscan2
- FGF20 | c.414C>A p.I138= | Silent (SNP) | VAF 48/288 reads (17%) | catalogued as COSV99471638; called by muse, mutect2, varscan2
- FGF5 | c.48C>T p.L16= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as rs1389936935, COSV56891520; called by muse, mutect2, varscan2
- FMNL2 | c.378G>C p.L126= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99980464; called by muse, mutect2, varscan2
- FRAS1 | c.4056C>T p.I1352= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99355087; called by muse, mutect2, varscan2
- FRMD6 | c.969C>G p.L323= (on ENST00000344768 / NM_001267046.2; = p.L315= on NM_152330.4) | Silent (SNP) | VAF 76/122 reads (62%) | catalogued as COSV100656183; called by muse, mutect2, varscan2
- FRY | c.3912C>G p.L1304= | Silent (SNP) | VAF 12/155 reads (8%) | catalogued as COSV100969785; called by muse, mutect2
- GLB1L3 | c.1410C>T p.H470= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs561657811, COSV101345155; called by muse, varscan2
- GPBAR1 | c.264C>G p.V88= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV99946471; called by muse, mutect2, varscan2
- GPR63 | c.744C>G p.L248= | Silent (SNP) | VAF 79/164 reads (48%) | catalogued as rs763452682, COSV100013534, COSV57739830; called by muse, mutect2, varscan2
- GRM1 | c.1365C>T p.I455= | Silent (SNP) | VAF 76/389 reads (20%) | catalogued as COSV51149466; called by muse, mutect2, varscan2
- GRM3 | c.1461A>T p.A487= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100862767; called by muse, mutect2, varscan2
- GRM4 | c.2628G>A p.K876= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV100946777; called by muse, mutect2, varscan2
- GSC | c.534C>T p.L178= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99450325; called by muse, mutect2, varscan2
- H2BW1 | c.507C>T p.A169= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as COSV99475134; called by muse, mutect2, varscan2
- HCN1 | c.1143C>G p.V381= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV100299239, COSV100301749, COSV57540975; called by muse, mutect2, varscan2
- HELZ | c.2082C>T p.L694= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV62380132; called by muse, mutect2, varscan2
- HNF1B | c.333C>T p.D111= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as rs1290584771; called by muse, mutect2, varscan2
- HS1BP3 | c.1095G>A p.Q365= | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as COSV100398074; called by muse, mutect2
- HS6ST3 | c.588C>G p.L196= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100941427; called by muse, mutect2, varscan2
169 further variants in this file (0 protein-altering or splice-affecting, 147 silent, 22 other) are not listed here.
